BEATAML1.0 case 2127 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myelodysplastic Syndromes; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/5460dcd4-34c0-48ee-991e-00d041c7b997

Demographics
Sex at birth: female.

Diagnoses (1)
1. Myelodysplastic syndrome, unclassifiable: ICD-O-3 morphology code: 9989/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.8 years (18,934 days); Progression or recurrence: no; ELN risk classification: Adverse.

Biospecimens (3 samples)
- Sample BA2143D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA2143R: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
- Sample BA2582D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
